Surgical pathology report (de-identified scan), TCGA case TCGA-T2-A6X0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site St. University of Colorado Denver, specimen TCGA-T2-A6X0-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site ~~CCF~~ Tonsil: NOS
C09.9
path
Overlapping lesion lip
oral cavity & pharynx C14.8
Male DOB: [redacted] 9/28/13
Department:

MRN [redacted]

Dept
Phone:
Encounter
#:

Description: Male DOB: [redacted]
Department:

Order Surgical Pathology Request
Entry Date

Result Narrative

FINAL DIAGNOSIS

- A) Tongue, glossotonsillar mass, biopsy:
- Invasive squamous cell carcinoma, moderately differentiated (see comments)
- B) Lymph nodes, right neck, selective neck dissection:
- Metastatic moderate to poorly differentiated squamous cell carcinoma (3.5 cm in greatest dimension), see comments
- Thirty one lymph nodes, negative for metastatic carcinoma (0/31)
- C) Tongue mass, right base, excision:
- Salivary gland parenchyma admixed with skeletal muscle, negative for malignancy

COMMENT

The frozen section slides from specimen A were reviewed and the carcinoma is not well represented on those slides. The large tumor mass in the right neck does not contain any lymphoid tissue within it, and may represent either a soft tissue tumor deposit or (more likely) a lymph node which has been completely replaced by tumor. If this is a replaced lymph node, there is extranodal extension of tumor into the surrounding soft tissue. Immunohistochemical preparations, with appropriately staining controls were performed on a representative section of tumor from specimen B and show the following results: Tumor cells are strongly and diffusely positive for p16 and show no circumferential membranous staining for EGFR. HPV studies have been ordered and the results will be issued in a separate report.

CLINICAL HISTORY

year-old male with recently diagnosed metastatic squamous cell carcinoma of the neck with a glossotonsillar mass.

GROSS DESCRIPTION

A) Received fresh for intraoperative consultation labeled with patient's name and medical record number designated "glossotonsillar mass," is one fragment of pink-tan soft tissue measuring 1.6 x 1.3 x 0.8 cm. The specimen is inked and bisected and submitted entirely for frozen section consultation. The frozen section remnant is submitted entirely in cassette (FSA1).

Reviewed (circle):	NOTIFIED	DISNOTIFIED

[page 2 of 4]
B) Received fresh for tissue banking, labeled with the patient's name and medical record number, and designated "right selective neck dissection, stitch marks 'Level 2,'" is a 38 g irregular tan-yellow fibroadipose tissue, 5.5 x 3 x 2.5 cm. A well-circumscribed 3.5 x 2.4 x 2.2 cm brown-red nodule is designated "Level 2," with a previously placed surgical stitch. The remainder of the tissue is irregular brown-red nodular fibroadipose tissue. Serial sectioning through the large nodule reveals tan-white homogeneous indurated cut surface. Lymph node dissection is performed on the remainder of the unremarkable nodular fibroadipose tissue. Sections are submitted as follows:

(B1-B2) Representative sections through large indurated mass
(B3) Five candidate lymph nodes
(B4) Four candidate lymph nodes
(B5) Four candidate lymph nodes
(B6) Four candidate lymph nodes
(B7-B16) Remaining fibroadipose soft tissue other than large indurated mass, submitted entirely

C) In formalin labeled [REDACTED] right base tongue," is a cauterized irregular rubbery skeletal muscle 1.5 x 1.2 x 0.6 cm. Tissue is inked black and is not oriented. Tissue is sectioned and submitted in its entirety as (C1).

INTRAOPERATIVE DIAGNOSIS

FSA1: Glossotonsillar mass: Benign

Intra-Operative Diagnosis Reviewed and Interpreted By:

'I certify that (1) all services on this form were rendered and are hereby approved for billing, (2) all specimens/slides have been examined / reviewed, (3) the medical record has been documented for these services, and (4) the rendering of the services and the documentation in the medical record are in accordance with guidelines.'

Final Diagnosis Reviewed and Interpreted by:

ELECTRONICALLY SIGNED

Pathologist

Date:

Some tests used in this case were developed in and their performance characteristics determined by the

. The procedures and reagents have been validated by evaluation of both negative and positive controls. This testing has not been

[REDACTED]

[page 3 of 4]
cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. Test results are used for clinical purposes. They should not be regarded as investigational or for research. The [redacted] is accredited by the College of American Pathologists and is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

"I certify that (1) all services on this form were rendered and are hereby approved for billing, (2) all specimens/slides have been examined / reviewed, (3) the medical record has been documented for these services, and (4) the rendering of the services and the documentation in the medical record are in accordance with [redacted] guidelines."

Lab and CollectionSurgical Pathology Request on**Specimen Information**

Specimen #

Collection Date

Received Date and Time

Resulting Agency

Reviewed by List**Surgical Pathology Request**

Ordering Physician

Provider Not In System

Result Information

Status

Provider Status

Final result

Reviewed

Surgery Report**Lab Printout**Open Hard Copy Result Report- Surgical Pathology Request**Order Report**View Order Information

MRN :

Hospital Encounter

Dept
Phone:
Encounter
#:

Description: Male DOB: [redacted]
Department:
Lab Collection Information

Collection Date

Lab IDs

Specimen #

[page 4 of 4]
Surgical Pathology Request

Lab

Authorizing:

Date and

Time:

Department:

Electronically

Signed By:

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Comments

Ordered by an unspecified provider

Order Details

Frequency

ONCE

Duration

1 occurrence

Priority

Routine

Order Class

Normal

Provider Information

Ordering User

Results Incoming

Ordering Provider

Authorizing Provider

Attending Provider(s)

Admitting Provider

Collection Information

Collection Date

Resulting Agency

Order ReportView Order Information

There are no specimens.

Reprint RequisitionsSurgical Pathology Requeston

Source: NCI Genomic Data Commons file efaf966d-be3f-4ee4-83d8-db15abfabed1 (TCGA-T2-A6X0.8C263A39-C697-4BBF-9444-ECBF56443CAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).